Somatic mutation profile of cancer-model specimen HCM-CSHL-0247-C18-85A (3D Organoid; aliquot HCM-CSHL-0247-C18-85A-01D-A78T-36), derived from the primary tumor of HCMI case HCM-CSHL-0247-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 76.5 years (27,936 days).
Specimen HCM-CSHL-0247-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29c30758-dd79-4413-b4c2-4507ecd4a5ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0247-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0247-C18-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e7c8ebb-8186-423d-bb47-94ea6f4a79e7

The open-access MAF lists 162 somatic variants for this specimen: 106 protein-altering or splice-affecting, 37 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 37, Intron 8, Nonsense Mutation 6, 5'UTR 5, RNA 3, Frame Shift Ins 2, 3'UTR 2, Frame Shift Del 1, In Frame Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 65/65 reads (100%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 583/584 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AL358113.1 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 183/367 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.121); catalogued as rs1037430967, COSV61957022; called by muse, mutect2, varscan2
- ALPK3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 286/286 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV51940688; called by muse, mutect2, varscan2
- AP1M2 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs761767257; called by muse, mutect2, varscan2
- ASAP1 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs1365555616; called by muse, mutect2, varscan2
- CACNA1A | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs756562814, COSV64200832, COSV64211473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAP2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs200521747, COSV57731947; called by muse, mutect2, varscan2
- CBY2 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 59/826 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.163); catalogued as rs1048522766, COSV60118086; called by muse, mutect2
- CDH23 | c.4519C>T p.R1507W | Missense Mutation (SNP) | VAF 122/250 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs760927863, COSV56477037; called by muse, mutect2, varscan2
- CDH7 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59880968; called by muse, mutect2, varscan2
- CLIC3 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs969745559; called by muse, mutect2, varscan2
- CNTN5 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 107/323 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as rs1398463099, COSV54329471; called by muse, mutect2, varscan2
- COG2 | c.1742G>A p.G581D | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV64186997; called by muse, mutect2
- COL4A2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 78/367 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs773576081; called by muse, mutect2, varscan2
- CPB1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs150860615, COSV99294138; called by muse, mutect2, varscan2
- CSMD3 | c.5836C>A p.R1946S (on ENST00000297405 / NM_001363185.1; = p.R1842S on NM_052900.3) | Missense Mutation (SNP) | VAF 173/296 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as rs377290204; called by muse, mutect2, varscan2
- DIPK1B | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 126/278 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770330516, COSV63038081; called by muse, mutect2, varscan2
- DLG2 | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 128/261 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV65832294, COSV65853967; called by muse, mutect2, varscan2
- EIF2B5 | c.1630G>A p.E544K (on ENST00000647909; = p.E536K on NM_003907.3) | Missense Mutation (SNP) | VAF 82/307 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as COSV56605595; called by muse, mutect2, varscan2
- GLI3 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 200/512 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); catalogued as rs1296035859, COSV67890481; called by muse, varscan2
- GLI3 | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 316/536 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs755227076, COSV67887250; ClinVar: uncertain significance; called by muse, varscan2
- GRM3 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs112122758, COSV100862026, COSV64478495; called by muse, mutect2, varscan2
- HLA-DOA | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as rs200140467; called by muse, mutect2
- HPCAL1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as COSV57145974; called by muse, mutect2, varscan2
- HTR7 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 129/231 reads (56%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as COSV53286886; called by muse, mutect2, varscan2
- MNDA | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as rs1329858284; called by muse, mutect2, varscan2
- MSLNL | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 94/209 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765899968, COSV53498896; called by muse, mutect2, varscan2
- NLRC5 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs866090118, COSV52660803; called by muse, mutect2
- NOL6 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 113/248 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs756516749; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.803G>A p.R268H (on ENST00000259318 / NM_001136562.3; = p.R499H on NM_007203.5) | Missense Mutation (SNP) | VAF 100/210 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs368590919; called by muse, mutect2, varscan2
- PCDHA12 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 236/520 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); catalogued as rs781787046, COSV56485542; called by muse, mutect2, varscan2
- PCDHGA6 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 230/513 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.052); catalogued as rs919176873, COSV53913907; called by muse, mutect2, varscan2
- PKD1L2 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 68/118 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.401); catalogued as rs779408230; called by muse, mutect2
- RIMBP2 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs763832408; called by muse, mutect2, varscan2
- RNF2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs1335456103, COSV62279097; called by muse, mutect2, varscan2
- SCG2 | c.1195T>G p.L399V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59538910, COSV59540439; called by muse, mutect2, varscan2
- SERPINB2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs922692149, COSV55091465; called by muse, mutect2
- SIN3A | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100845221; called by muse, mutect2, varscan2
- SLC6A2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 170/383 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776659407, COSV54923884; called by muse, mutect2, varscan2
- SOX9 | c.1261_1267dup p.F423* | Frame Shift Ins (INS) | VAF 108/126 reads (86%) | catalogued as COSV55427921; called by mutect2, varscan2
- SPDEF | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 99/209 reads (47%) | catalogued as rs770126986, COSV100927845; called by muse, mutect2, varscan2
- TBXA2R | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 223/625 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1249340215, COSV64344628; called by muse, mutect2, varscan2
- TENM2 | c.2416G>A p.E806K (on ENST00000518659 / NM_001122679.2; = p.E574K on NM_001080428.3) | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs376627738; called by muse, mutect2, varscan2
- TNXB | c.5065G>A p.G1689S (on ENST00000647633; = p.G1442S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762480960; called by muse, mutect2, varscan2
- TRPV6 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100844260; called by muse, mutect2, varscan2
- UBAP1L | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 139/139 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs933188149; called by muse, mutect2, varscan2
- USP13 | c.1966T>G p.S656A | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.044); catalogued as rs750485320; called by muse, mutect2, varscan2
- WDR7 | c.4364C>T p.A1455V | Missense Mutation (SNP) | VAF 121/121 reads (100%) | SIFT tolerated (0.64); PolyPhen benign (0.181); catalogued as rs750926404; called by muse, mutect2, varscan2
- ZNF251 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 151/226 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs200114017; called by muse, mutect2, varscan2
- ZNF747 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 249/539 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs890550251, COSV53224406; called by muse, mutect2, varscan2
- APC | c.3209del p.N1070Ifs*56 | Frame Shift Del (DEL) | VAF 86/118 reads (73%) | called by mutect2, pindel, varscan2
- APOB | c.10788G>T p.M3596I | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C6orf89 | c.933A>G p.I311M (on ENST00000373685; = p.I318M on NM_152734.4) | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CARMIL3 | c.3118T>G p.S1040A | Missense Mutation (SNP) | VAF 97/416 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC150 | c.2330A>C p.Q777P | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCER1 | c.606G>T p.R202S | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CLASP2 | c.4067C>G p.A1356G (on ENST00000359576; = p.A1355G on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- CMKLR1 | c.920C>G p.A307G (on ENST00000312143 / NM_001142344.2; = p.A305G on NM_004072.3) | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- COL6A5 | c.2828A>G p.N943S | Missense Mutation (SNP) | VAF 220/347 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CTNNA3 | c.1652T>A p.V551D | Missense Mutation (SNP) | VAF 150/298 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DACT2 | c.2024dup p.S676Vfs*13 | Frame Shift Ins (INS) | VAF 45/132 reads (34%) | called by mutect2, pindel, varscan2
- EPHA5 | c.2107C>G p.P703A | Missense Mutation (SNP) | VAF 53/53 reads (100%) | SIFT tolerated (0.49); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM217B | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 254/386 reads (66%) | SIFT tolerated (0.33); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- FAM72B | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 117/244 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GAPDH | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 83/255 reads (33%) | called by muse, mutect2, varscan2
- GRM1 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM5 | c.1381G>C p.D461H | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HELZ | c.2752T>A p.F918I | Missense Mutation (SNP) | VAF 101/101 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- HTR3A | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); called by muse, varscan2
- IL12RB1 | c.646G>T p.G216W | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- INHBA | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 188/354 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ITGA9 | c.88T>A p.Y30N | Missense Mutation (SNP) | VAF 143/143 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ITGB3 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 217/484 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF13A | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- L3MBTL4 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LRRC24 | c.426_428del p.F142del | In Frame Del (DEL) | VAF 130/434 reads (30%) | called by pindel, varscan2
- MAP1A | c.6785A>G p.E2262G | Missense Mutation (SNP) | VAF 431/432 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- NKTR | c.3205A>G p.K1069E | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTM | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 103/210 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NTRK3 | c.2167T>A p.W723R | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.86); called by muse, varscan2
- PCDH19 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PHRF1 | c.2165A>T p.Q722L (on ENST00000264555 / NM_001286581.2; = p.Q721L on NM_020901.4) | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PLEKHG6 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- PPP1CB | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- PPP2R1A | c.1180G>T p.V394L | Missense Mutation (SNP) | VAF 82/83 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PTPRT | c.2973A>C p.E991D | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- RAPGEF6 | c.4715G>C p.R1572T | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- SALL3 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SLC22A4 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 196/198 reads (99%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLIT1 | c.2627G>A p.W876* | Nonsense Mutation (SNP) | VAF 124/222 reads (56%) | called by muse, mutect2, varscan2
- SMG1 | c.9077T>A p.L3026Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SPART | c.566C>G p.T189R | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SSBP4 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SSC5D | c.2251T>C p.S751P | Missense Mutation (SNP) | VAF 52/52 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TAF1C | c.408G>T p.G136= | Splice Region (SNP) | VAF 85/197 reads (43%) | called by muse, mutect2, varscan2
- TEX51 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TMEM209 | c.1541T>C p.V514A | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.055); called by muse, mutect2
- UHRF1BP1L | c.4276-2A>T p.X1426_splice | Splice Site (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- USP48 | c.2680A>G p.K894E | Missense Mutation (SNP) | VAF 106/106 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UST | c.777C>A p.C259* | Nonsense Mutation (SNP) | VAF 83/172 reads (48%) | called by muse, mutect2
- XKR7 | c.721G>C p.A241P | Missense Mutation (SNP) | VAF 46/560 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZIK1 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- ZNF292 | c.6326G>C p.S2109T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2
- A4GNT | c.513C>T p.I171= | Silent (SNP) | VAF 110/380 reads (29%) | called by muse, mutect2, varscan2
- ABCG4 | c.78C>T p.D26= | Silent (SNP) | VAF 151/299 reads (51%) | catalogued as rs373824430; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1791G>A p.G597= | Silent (SNP) | VAF 114/244 reads (47%) | called by muse, mutect2, varscan2
- ANKEF1 | c.1071C>T p.N357= | Silent (SNP) | VAF 55/182 reads (30%) | catalogued as rs937679166; called by muse, mutect2, varscan2
- APOBEC3F | c.708C>T p.G236= | Silent (SNP) | VAF 64/130 reads (49%) | catalogued as COSV57910186; called by muse, mutect2
- CTNNA2 | c.351G>A p.S117= | Silent (SNP) | VAF 109/232 reads (47%) | catalogued as rs201020471, COSV63548922; called by muse, mutect2, varscan2
- CYP2D6 | c.264C>T p.R88= | Silent (SNP) | VAF 313/1028 reads (30%) | catalogued as rs1230147351; called by muse, mutect2, varscan2
- DAB2 | c.1386C>T p.P462= | Silent (SNP) | VAF 103/201 reads (51%) | catalogued as rs1232950773, COSV57917425; called by muse, mutect2, varscan2
- DPP10 | c.1321C>T p.L441= | Silent (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- EML3 | c.1587G>C p.L529= | Silent (SNP) | VAF 55/165 reads (33%) | called by muse, mutect2, varscan2
- FAM161A | c.90C>T p.Y30= | Silent (SNP) | VAF 204/435 reads (47%) | called by muse, mutect2, varscan2
- FAM227A | c.639G>A p.Q213= | Silent (SNP) | VAF 50/123 reads (41%) | called by muse, mutect2, varscan2
- FAT3 | c.11919G>A p.T3973= | Silent (SNP) | VAF 128/269 reads (48%) | catalogued as rs898299684, COSV53101021; called by muse, mutect2, varscan2
- FOXO1 | c.1746C>T p.S582= | Silent (SNP) | VAF 89/107 reads (83%) | called by muse, mutect2, varscan2
- FRY | c.6315G>A p.L2105= | Silent (SNP) | VAF 68/306 reads (22%) | called by muse, mutect2, varscan2
- GAB4 | c.72G>A p.S24= | Silent (SNP) | VAF 86/214 reads (40%) | catalogued as rs1182743180; called by muse, mutect2, varscan2
- GALNT14 | c.1587C>T p.N529= | Silent (SNP) | VAF 89/235 reads (38%) | catalogued as rs145219116; called by muse, mutect2, varscan2
- GATA5 | c.675G>A p.P225= | Silent (SNP) | VAF 217/610 reads (36%) | catalogued as rs144082730; called by muse, mutect2, varscan2
- GGT6 | c.780C>T p.S260= (on ENST00000574154 / NM_001122890.3; = p.S228= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/140 reads (49%) | catalogued as rs768266892, COSV99626686; called by muse, mutect2, varscan2
- HECW2 | c.1914G>A p.L638= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV53651191; called by muse, mutect2, varscan2
- LMNB1 | c.1332C>T p.I444= | Silent (SNP) | VAF 104/239 reads (44%) | catalogued as rs779989576; called by muse, mutect2, varscan2
- MC2R | c.504C>T p.F168= | Silent (SNP) | VAF 86/86 reads (100%) | called by muse, mutect2, varscan2
- MESP1 | c.231C>T p.S77= | Silent (SNP) | VAF 156/156 reads (100%) | called by muse, mutect2, varscan2
- MUC12 | c.4041C>T p.D1347= (on ENST00000379442; = p.D1204= on NM_001164462.1) | Silent (SNP) | VAF 177/661 reads (27%) | catalogued as rs1468499227; called by muse, mutect2, varscan2
- MYT1L | c.816C>T p.H272= | Silent (SNP) | VAF 84/159 reads (53%) | catalogued as rs751168400, COSV67728872; called by muse, mutect2, varscan2
- NPL | c.324C>T p.I108= | Silent (SNP) | VAF 143/280 reads (51%) | catalogued as rs369901524; called by muse, mutect2, varscan2
- OCM2 | c.15C>T p.D5= | Silent (SNP) | VAF 57/178 reads (32%) | catalogued as rs762988500, COSV57535963; called by muse, mutect2, varscan2
- PCDHB15 | c.1857G>A p.A619= | Silent (SNP) | VAF 126/640 reads (20%) | catalogued as rs1217877580, COSV50865650; called by muse, mutect2, varscan2
- PIEZO2 | c.2976G>T p.V992= | Silent (SNP) | VAF 73/73 reads (100%) | called by muse, mutect2, varscan2
- PPT1 | c.363G>A p.R121= (on ENST00000433473; = p.R122= on NM_000310.4) | Silent (SNP) | VAF 171/171 reads (100%) | called by muse, mutect2, varscan2
- PRADC1 | c.237C>T p.N79= | Silent (SNP) | VAF 113/289 reads (39%) | catalogued as rs753244246; called by muse, mutect2, varscan2
- PROKR2 | c.420C>T p.Y140= | Silent (SNP) | VAF 66/208 reads (32%) | catalogued as rs199794008, CM085658; called by muse, mutect2, varscan2
- SOX8 | c.915C>T p.G305= | Silent (SNP) | VAF 88/182 reads (48%) | catalogued as rs372544446, COSV53509080, COSV53510314; called by muse, mutect2
- TOP3B | c.2136C>G p.P712= | Silent (SNP) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- TRPM2 | c.2292G>A p.P764= | Silent (SNP) | VAF 100/189 reads (53%) | catalogued as rs148173972; called by muse, mutect2, varscan2
- USP2 | c.705G>A p.T235= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs752095300, COSV52730776; called by muse, mutect2, varscan2
- WDR13 | c.456G>A p.T152= | Silent (SNP) | VAF 155/155 reads (100%) | catalogued as rs1556993839; called by muse, mutect2, varscan2
- ABCC13 | n.3985A>C | RNA (SNP) | VAF 62/188 reads (33%) | catalogued as rs1182343970; called by muse, mutect2, varscan2
- BCAS1 | c.927+2412C>A | Intron (SNP) | VAF 115/515 reads (22%) | called by muse, mutect2, varscan2
- C9orf62 | n.511G>T | RNA (SNP) | VAF 74/162 reads (46%) | catalogued as rs1011518817; called by muse, mutect2, varscan2
- CCDC169 | chr13:36227319 C>G | 3'Flank (SNP) | VAF 43/266 reads (16%) | called by muse, mutect2, varscan2
- CGB8 | c.-12G>T | 5'UTR (SNP) | VAF 100/102 reads (98%) | catalogued as rs200172544; called by muse, mutect2, varscan2
- CINP | c.-11C>T | 5'UTR (SNP) | VAF 57/57 reads (100%) | catalogued as rs781568572; called by muse, mutect2, varscan2
- CPNE2 | c.928-520C>T | Intron (SNP) | VAF 77/216 reads (36%) | called by muse, mutect2, varscan2
- ESPNP | n.1386G>A | RNA (SNP) | VAF 7/34 reads (21%) | catalogued as rs1332472098; called by muse, varscan2
- FSHB | c.-1G>A | 5'UTR (SNP) | VAF 87/175 reads (50%) | called by muse, mutect2, varscan2
- GYPB | c.37+2403G>T | Intron (SNP) | VAF 24/24 reads (100%) | called by muse, mutect2, varscan2
- IKBKB | c.1516+42T>G | Intron (SNP) | VAF 221/317 reads (70%) | called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.*186C>G | 3'UTR (SNP) | VAF 90/279 reads (32%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.-23G>A | 5'UTR (SNP) | VAF 190/370 reads (51%) | called by muse, mutect2, varscan2
- PLCG2 | c.2307+89C>A | Intron (SNP) | VAF 101/226 reads (45%) | called by muse, mutect2, varscan2
- PLSCR2 | c.-20G>A | 5'UTR (SNP) | VAF 17/84 reads (20%) | called by muse, mutect2, varscan2
- SFXN5 | c.945+4098C>T | Intron (SNP) | VAF 71/166 reads (43%) | catalogued as rs1037813559; called by muse, mutect2, varscan2
- SLFN11 | c.1198+12T>C | Intron (SNP) | VAF 38/124 reads (31%) | called by muse, mutect2, varscan2
- TMEM120A | c.*67C>T | 3'UTR (SNP) | VAF 60/103 reads (58%) | catalogued as rs782267943; called by muse, mutect2, varscan2
- ZFHX4 | c.3093+87G>T | Intron (SNP) | VAF 16/92 reads (17%) | catalogued as rs781204964; called by muse, varscan2
